Gene-level copy-number profile of tumor specimen ALCH-AEYV-TTR1-A from ALCHEMIST case ALCH-AEYV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.9 years (23,348 days).
Specimen ALCH-AEYV-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 940f93fc-9e9f-4153-b28f-bcf30bf757cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEYV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/47af58c1-47e4-4e1d-9100-ec0b00ebbf69

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 17,916; copy number 2: 34,349; copy number 3: 5,207; copy number 4: 576; copy number 5: 285; copy number 7: 6; copy number 9: 5.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,896,654–29,926,973, 4 genes (within-gene range 0–1): HLA-T, DDX39BP1, MCCD1P1, HCG4B.
- chr9:66,942,703–66,988,373, 5 genes (within-gene range 0–1): AL353770.4, AL353770.2, FAM74A3, AL353770.3, AL353770.1.
- chr9:67,059,560–67,329,404, 5 genes: CNTNAP3P2, RN7SL422P, AL162233.1, RBM17P2, BX005195.1.
- chr9:124,853,417–124,861,981, 2 genes: WDR38, RPL35.
- chr13:78,285,838–78,286,288, 1 gene (within-gene range 0–1): SRGNP1.
- chr14:103,529,196–103,550,406, 2 genes: TRMT61A, RNU7-160P.
- chr16:29,995,715–30,027,736, 3 genes (within-gene range 0–1): INO80E, DOC2A, C16orf92.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr19:58,034,025–58,054,631, 3 genes: ZSCAN1, LETM1P2, HNRNPDLP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 296 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:87,620,803–88,685,204, 1 gene, copy number 5 (within-gene range 4–5): PKN2-AS1.
- chr1:88,684,222–94,592,297, 130 genes, copy number 5–7 (broad region; genes not listed).
- chr1:190,478,551–193,106,114, 31 genes, copy number 5–9: LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2.
- chr5:1,309,310–1,445,440, 6 genes, copy number 5: MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3.
- chr5:29,516,005–30,365,684, 9 genes, copy number 5: AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1.
- chr6:52,664,366–53,418,737, 39 genes, copy number 5: AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2, GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3, GSTA9P, GSTA4, 7SK, RN7SK, CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20, ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3.
- chr6:60,281,444–60,546,660, 1 gene, copy number 5: AC244258.1.
- chr11:68,460,731–70,398,488, 55 genes, copy number 5 (within-gene range 4–11): PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:46,469,341–46,621,379, 5 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1.
- chr21:10,413,477–13,120,807, 12 genes, copy number 5: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:28,742,039–28,800,597, 3 genes, copy number 5 (within-gene range 2–5): HSCB, CCDC117, XBP1.

Autosomal genes at a single copy (total copy number 1): 17,890. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
